Somatic mutation profile of tumor specimen MP2PRT-PASXUP-TMP1-A (aliquot MP2PRT-PASXUP-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASXUP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,151 days).
Specimen MP2PRT-PASXUP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a360806a-b634-47f5-b83c-fd24ca8f91e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASXUP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASXUP-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/404aee7e-555e-43e9-b735-5e9310ba5a58

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD34A | c.853C>G p.R285G | Missense Mutation (SNP) | VAF 64/515 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.088); catalogued as rs782039215, COSV60161834; called by muse, mutect2, varscan2
- OR5B12 | c.273A>T p.L91F | Missense Mutation (SNP) | VAF 167/377 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs368685605; called by muse, mutect2, varscan2
- PPBP | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs201755460, COSV56020140; called by muse, mutect2, varscan2
- ACVR2A | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 137/347 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CD177 | c.1104C>A p.S368R | Missense Mutation (SNP) | VAF 126/270 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNKSR2 | c.2984A>C p.D995A | Missense Mutation (SNP) | VAF 150/392 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- GIP | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHOX2B | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- PRPF3 | c.953C>G p.A318G | Missense Mutation (SNP) | VAF 117/322 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- BARD1 | c.1875C>T p.L625= | Silent (SNP) | VAF 18/283 reads (6%) | catalogued as rs1396679779, COSV53613767; ClinVar: likely benign; called by muse, mutect2
- FBXL2 | c.666G>A p.T222= | Silent (SNP) | VAF 28/312 reads (9%) | catalogued as rs187890901; called by muse, mutect2
- OR8B12 | c.663C>A p.L221= | Silent (SNP) | VAF 18/478 reads (4%) | catalogued as rs984938943, COSV60912151; called by muse, mutect2
- RAPGEFL1 | c.528G>A p.L176= | Silent (SNP) | VAF 83/293 reads (28%) | called by muse, mutect2, varscan2
- TMEM132B | c.1644C>T p.S548= | Silent (SNP) | VAF 110/261 reads (42%) | catalogued as rs767749096, COSV54773325; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins TCCCGCC | 3'Flank (INS) | VAF 22/107 reads (21%) | called by mutect2, pindel
